Somatic mutation profile of tumor specimen MP2PRT-PAUJDW-TMP1-A (aliquot MP2PRT-PAUJDW-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUJDW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (638 days).
Specimen MP2PRT-PAUJDW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a112281b-9260-4d18-ae81-4d591b19de74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJDW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJDW-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/047c52f7-9feb-4f97-b83d-427f51311dd0

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HCN4 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 96/412 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs528148663, COSV56083188; called by muse, mutect2, varscan2
- KLHL1 | c.1729A>C p.S577R | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as rs1206559942; called by muse, mutect2, varscan2
- PDZD2 | c.2416G>A p.V806I | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766010611, COSV56850984; called by muse, mutect2, varscan2
- PROKR2 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs748456023, COSV54089508; called by muse, mutect2, varscan2
- RIMBP2 | c.2205G>A p.P735= | Splice Region (SNP) | VAF 44/220 reads (20%) | catalogued as rs756144691, COSV55470457; called by muse, mutect2, varscan2
- UNC80 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760417182, COSV55897072; called by muse, mutect2, varscan2
- FSIP2 | c.16927G>C p.D5643H | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IGHV2-26 | chr14:106301394 del GGTATCCGTGC | Missense Mutation (DEL) | VAF 26/245 reads (11%) | called by mutect2, pindel*, varscan2
- LTF | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 14/377 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA13 | c.1076T>G p.I359S | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IGHV3-23 | c.352del p.*118= | Silent (DEL) | VAF 39/250 reads (16%) | called by mutect2, pindel*
- IGKV1OR2-108 | chr2:113406871 del TTCAC | Silent (DEL) | VAF 30/152 reads (20%) | called by pindel, varscan2
- LNPEP | c.2136A>G p.L712= | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as COSV51479588; called by muse, mutect2
- MYOZ2 | c.480G>A p.P160= | Silent (SNP) | VAF 139/294 reads (47%) | catalogued as rs779726933; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937679 ins GCGGC | 3'Flank (INS) | VAF 24/104 reads (23%) | called by pindel, varscan2
